Somatic mutation profile of tumor specimen ALCH-B1UT-TTP1-A (aliquot ALCH-B1UT-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1UT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.5 years (24,666 days).
Specimen ALCH-B1UT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89078c5f-bb14-4e38-be00-77234fc81b85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UT-NB1-A (Blood Derived Normal), aliquot ALCH-B1UT-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c77b7c-b9d2-456e-8052-e517523af6da

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRF | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 58/1650 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54837799, COSV99542044; called by muse, mutect2
- CRACR2A | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 22/874 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- GEMIN5 | c.1996-1G>C p.X666_splice | Splice Site (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- HPS3 | c.217+25C>T | Intron (SNP) | VAF 16/318 reads (5%) | called by muse, mutect2
